Somatic mutation profile of tumor specimen MMRF_1377_1_BM_CD138pos (aliquot MMRF_1377_1_BM_CD138pos_T1_KAS5U_L00687) from MMRF case MMRF_1377, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.8 years (24,780 days).
Specimen MMRF_1377_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b7e83ae-417d-4dc1-a245-9ec08f495364.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1377_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1377_1_PB_Whole_C2_KAS5U_L00695; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59b04fcf-af4b-42fc-9a0c-6b1ecda1888c

The open-access MAF lists 299 somatic variants for this specimen: 122 protein-altering or splice-affecting, 29 silent, 148 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, 3'UTR 80, Intron 34, Silent 29, 5'UTR 13, 5'Flank 10, Frame Shift Del 7, RNA 7, Nonsense Mutation 4, Splice Site 4, Splice Region 4, 3'Flank 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.3062C>T p.S1021F | Missense Mutation (SNP) | VAF 97/203 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as rs751029124, COSV67131471; called by muse, mutect2, varscan2
- AKAP3 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 70/146 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs370794366; called by muse, mutect2, varscan2
- ANKRD34B | c.1342T>G p.F448V | Missense Mutation (SNP) | VAF 88/178 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs751004433; called by muse, mutect2, varscan2
- ANO5 | c.748T>C p.Y250H | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1265518780; called by muse, mutect2, varscan2
- ATP2B4 | c.2263C>T p.R755* | Nonsense Mutation (SNP) | VAF 62/114 reads (54%) | catalogued as rs756353643, COSV58180406; called by muse, mutect2, varscan2
- BAHCC1 | c.2723G>A p.G908D | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1555653949; called by mutect2, varscan2
- COL24A1 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 47/54 reads (87%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.828); catalogued as rs1427068654; called by muse, mutect2, varscan2
- COPB1 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.1); catalogued as rs1419001709; called by muse, mutect2, varscan2
- COPS5 | c.921-5dup | Splice Region (INS) | VAF 33/41 reads (80%) | catalogued as rs200155628; called by mutect2, varscan2
- DAPK3 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.639); catalogued as rs546562367; called by muse, mutect2, varscan2
- DEPDC1 | c.1840C>G p.R614G (on ENST00000456315 / NM_001114120.3; = p.R330G on NM_017779.6) | Missense Mutation (SNP) | VAF 34/34 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV63957625; called by muse, mutect2, varscan2
- DGKI | c.3070A>G p.T1024A | Missense Mutation (SNP) | VAF 84/166 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.803); catalogued as rs200109920; called by muse, mutect2, varscan2
- EPHB6 | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV67420808; called by muse, mutect2, varscan2
- EPPK1 | c.2497G>A p.A833T | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.24); catalogued as rs782549936; called by muse, mutect2
- FLT3 | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 28/33 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99609429; called by muse, mutect2, varscan2
- FOCAD | c.1598T>A p.L533H | Missense Mutation (SNP) | VAF 62/125 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58100518; called by muse, mutect2, varscan2
- GUCY1A2 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 92/182 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs763071550, COSV56489770; called by muse, mutect2, varscan2
- H3C4 | c.378G>C p.Q126H | Missense Mutation (SNP) | VAF 85/238 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.073); catalogued as rs1271682139, COSV61912355; called by muse, mutect2, varscan2
- HS6ST1 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.152); catalogued as rs557526954, COSV52128230; called by muse, mutect2, varscan2
- IGLV3-1 | c.314A>C p.Y105S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs185803370; called by muse, varscan2
- IGLV5-45 | c.89C>G p.S30C | Missense Mutation (SNP) | VAF 107/124 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761763804; called by muse, varscan2
- IGLV5-45 | c.362G>C p.S121T | Missense Mutation (SNP) | VAF 82/124 reads (66%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs776960242; called by muse, varscan2
- IGLV6-57 | c.194C>T p.T65I | Missense Mutation (SNP) | VAF 64/79 reads (81%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.828); catalogued as rs751441839, COSV66504024; called by muse, varscan2
- IGLV7-46 | c.318G>C p.E106D | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs112695317; called by muse, varscan2
- IRX2 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.023); catalogued as rs1384306505; called by muse, mutect2, varscan2
- ITGA11 | c.1798G>A p.G600S | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.905); catalogued as rs767369353; called by muse, mutect2, varscan2
- MAP1A | c.8138G>A p.R2713H | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs761561997, COSV104393531; called by muse, mutect2, varscan2
- MARS1 | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 72/124 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs369861995; called by muse, mutect2, varscan2
- MEF2C | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 79/170 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs777826971, COSV100425377; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MPDZ | c.4576G>A p.G1526R | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs758008321; called by muse, mutect2, varscan2
- MPRIP | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs142740063; called by muse, mutect2, varscan2
- MUC16 | c.40015G>A p.D13339N | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.932); catalogued as rs1318573658, COSV66690129; called by muse, mutect2
- MUSK | c.1088G>T p.S363I | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV51880043; called by muse, mutect2, varscan2
- MYO15B | c.7183C>T p.R2395W | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs967140382; called by muse, mutect2, varscan2
- NCKIPSD | c.172-3dup | Splice Region (INS) | VAF 16/50 reads (32%) | catalogued as rs768132931; called by mutect2, varscan2
- NUP133 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs376867486; called by muse, mutect2, varscan2
- OR52D1 | c.92C>A p.A31D | Missense Mutation (SNP) | VAF 109/226 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV59486919; called by muse, mutect2, varscan2
- PIK3R5 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1467514002, COSV99353893; called by muse, mutect2, varscan2
- PLCB3 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1192862173, COSV54185686; called by muse, mutect2, varscan2
- PPP1R26 | c.2752G>A p.G918S | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs376123255; called by muse, mutect2, varscan2
- PRDM4 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV99946742; called by muse, mutect2, varscan2
- SDK2 | c.3655C>T p.R1219C | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs752844828; called by muse, mutect2, varscan2
- SOX9 | c.1376G>A p.G459D | Missense Mutation (SNP) | VAF 90/254 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as rs1298027378, COSV55422986; called by muse, mutect2, varscan2
- STK33 | c.1448G>A p.G483E | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs1459256404, COSV59397127, COSV59403265; called by muse, mutect2, varscan2
- TMC4 | c.583C>A p.P195T (on ENST00000617472 / NM_001145303.3; = p.P189T on NM_144686.4) | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.511); catalogued as COSV55475798; called by muse, mutect2, varscan2
- UGT1A8 | c.364del p.S122Rfs*12 | Frame Shift Del (DEL) | VAF 80/179 reads (45%) | catalogued as rs762306873; called by mutect2, pindel, varscan2
- UNC13C | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 77/155 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs749267979, COSV52888489; called by muse, mutect2, varscan2
- URGCP | c.1588C>T p.R530W (on ENST00000453200 / NM_001077663.3; = p.R521W on NM_017920.4) | Missense Mutation (SNP) | VAF 80/159 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as rs1414683505, COSV99787249; called by muse, mutect2, varscan2
- WNT9B | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 76/151 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs773812928; called by muse, mutect2, varscan2
- XIRP1 | c.2939T>A p.M980K | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs752483093; called by muse, mutect2, varscan2
- ZFHX4 | c.6661G>A p.D2221N | Missense Mutation (SNP) | VAF 94/108 reads (87%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV51460666; called by muse, mutect2, varscan2
- ZFP37 | c.482del p.N161Ifs*24 | Frame Shift Del (DEL) | VAF 35/91 reads (38%) | catalogued as rs563751025; called by mutect2, varscan2
- ZNF407 | c.6568G>A p.V2190M | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.735); catalogued as rs199702750, COSV100225428; called by muse, mutect2, varscan2
- ZNF835 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.278); catalogued as rs1443280493; called by muse, mutect2, varscan2
- ABCA5 | c.4227del p.M1409Ifs*5 | Frame Shift Del (DEL) | VAF 36/87 reads (41%) | called by mutect2, pindel, varscan2
- ARHGAP21 | c.1040A>C p.K347T | Missense Mutation (SNP) | VAF 79/145 reads (54%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ART5 | c.305C>A p.S102* | Nonsense Mutation (SNP) | VAF 63/144 reads (44%) | called by muse, mutect2, varscan2
- ASTN2 | c.1979G>A p.G660E (on ENST00000313400 / NM_001365069.1; = p.G609E on NM_014010.5) | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C2CD3 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- CAMK2N2 | c.238T>G p.*80Eext*79 | Nonstop Mutation (SNP) | VAF 71/150 reads (47%) | called by muse, mutect2, varscan2
- CATSPERD | c.904+1_904+16del p.X302_splice | Splice Site (DEL) | VAF 64/168 reads (38%) | called by mutect2, pindel, varscan2
- CCDC39 | c.876A>T p.K292N | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.45); called by muse, mutect2
- CD36 | c.928T>G p.Y310D | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDKN2C | c.203_206del p.R68Lfs*55 | Frame Shift Del (DEL) | VAF 49/66 reads (74%) | called by mutect2, pindel, varscan2
- CIT | c.4889G>T p.G1630V | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2
- CNBD2 | c.1425T>A p.N475K (on ENST00000373973 / NM_001365709.1; = p.N471K on NM_080834.4) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTN3 | c.1659A>T p.K553N | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- CRTC2 | c.1801A>T p.N601Y | Missense Mutation (SNP) | VAF 108/229 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- DENND3 | c.2465A>C p.K822T | Missense Mutation (SNP) | VAF 18/19 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DGKK | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 43/45 reads (96%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSTYK | c.941G>T p.S314I | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- EFNB1 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 42/43 reads (98%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EHD1 | c.392_394delinsA p.A131Dfs*39 | Frame Shift Del (DEL) | VAF 29/75 reads (39%) | called by pindel, varscan2*
- EIF2AK3 | c.3213_3215del p.I1072del | In Frame Del (DEL) | VAF 162/256 reads (63%) | called by pindel, varscan2
- EMILIN1 | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 76/173 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- ENPP7 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- EXOSC10 | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 44/45 reads (98%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- FOXL3 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- GLUL | c.526G>C p.V176L | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GPR88 | c.960dup p.S321Qfs*67 | Frame Shift Ins (INS) | VAF 39/58 reads (67%) | called by pindel, varscan2
- H4C5 | c.92C>T p.T31I | Missense Mutation (SNP) | VAF 107/209 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- HOMER1 | c.850A>G p.R284G | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- IGF1R | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IGLV7-46 | c.225A>T p.K75N | Missense Mutation (SNP) | VAF 57/68 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.335); called by muse, varscan2
- ITPR2 | c.7163T>A p.V2388D | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM3A | c.1519+2T>G p.X507_splice | Splice Site (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
- KIAA0319 | c.1831G>T p.A611S | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- MAMDC2 | c.1498G>C p.E500Q | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- MPL | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.09); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- MRPL50 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MTMR8 | c.468G>A p.E156= | Splice Region (SNP) | VAF 77/79 reads (97%) | called by muse, mutect2, varscan2
- MYO15A | c.2105C>T p.P702L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO15B | c.7032G>T p.Q2344H | Missense Mutation (SNP) | VAF 96/191 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP13 | c.2953C>T p.L985F | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR6C6 | c.108C>A p.S36R | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- OR7G1 | c.105C>G p.Y35* | Nonsense Mutation (SNP) | VAF 49/107 reads (46%) | called by muse, mutect2, varscan2
- PCLO | c.13405C>A p.H4469N | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- PHIP | c.1652A>G p.K551R | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PIWIL1 | c.1908C>A p.D636E | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRZ1 | c.4960G>T p.V1654F | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- PXMP4 | c.177-4G>C | Splice Region (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2
- RNGTT | c.367+2T>A p.X123_splice | Splice Site (SNP) | VAF 57/114 reads (50%) | called by muse, mutect2, varscan2
- ROBO2 | c.1589T>G p.V530G | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SAYSD1 | c.209A>G p.E70G | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEC63 | c.1490_1492del p.A497del | In Frame Del (DEL) | VAF 46/78 reads (59%) | called by pindel, varscan2
- SGO2 | c.1083T>A p.Y361* | Nonsense Mutation (SNP) | VAF 66/131 reads (50%) | called by muse, mutect2, varscan2
- SLC39A4 | c.1066del p.V356Sfs*10 (on ENST00000301305 / NM_001374839.1; = p.V331Sfs*10 on NM_017767.3) | Frame Shift Del (DEL) | VAF 36/51 reads (71%) | called by mutect2, pindel, varscan2
- SPANXB1 | c.38G>A p.S13N | Missense Mutation (SNP) | VAF 104/337 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- SPATA31D1 | c.2985A>T p.Q995H | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- STRADB | c.193+2T>C p.X65_splice | Splice Site (SNP) | VAF 50/91 reads (55%) | called by muse, mutect2, varscan2
- TENT5C | c.16dup p.S6Kfs*18 | Frame Shift Ins (INS) | VAF 32/159 reads (20%) | called by mutect2, pindel, varscan2
- TENT5C | c.472_474del p.S158del | In Frame Del (DEL) | VAF 66/91 reads (73%) | called by mutect2, pindel, varscan2
- TENT5C | c.872_876del p.Y291Sfs*6 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel
- TMX3 | c.1127T>G p.L376R | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- TNFSF12 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTLL11 | c.1191A>C p.L397F | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- USP22 | c.940T>G p.C314G | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP28 | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDFY3 | c.5063T>C p.M1688T | Missense Mutation (SNP) | VAF 72/78 reads (92%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ZCCHC2 | c.2446A>C p.K816Q | Missense Mutation (SNP) | VAF 84/177 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZEB1 | c.1857_1858insAAAAC p.L620Kfs*7 | Frame Shift Ins (INS) | VAF 91/172 reads (53%) | called by mutect2, pindel, varscan2
- ZFP36 | c.497C>T p.S166F (on ENST00000594442; = p.S160F on NM_003407.5) | Missense Mutation (SNP) | VAF 119/260 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABCA13 | c.2256C>T p.S752= | Silent (SNP) | VAF 63/136 reads (46%) | called by muse, mutect2, varscan2
- ADRA1D | c.1569C>T p.A523= | Silent (SNP) | VAF 56/115 reads (49%) | catalogued as rs771496988, COSV101063147; called by muse, mutect2, varscan2
- ALPG | c.717C>T p.D239= | Silent (SNP) | VAF 69/120 reads (58%) | called by muse, mutect2, varscan2
- CROCC2 | c.495C>T p.T165= | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as rs775643047; called by muse, mutect2
- ELP5 | c.681C>G p.L227= | Silent (SNP) | VAF 46/114 reads (40%) | called by muse, mutect2, varscan2
- EVI5 | c.1875C>G p.L625= | Silent (SNP) | VAF 41/46 reads (89%) | called by muse, mutect2, varscan2
- FREM1 | c.5658T>A p.T1886= | Silent (SNP) | VAF 8/155 reads (5%) | called by muse, mutect2
- IGLV6-57 | c.195C>A p.T65= | Silent (SNP) | VAF 62/80 reads (78%) | called by muse, varscan2
- IGLV6-57 | c.276T>C p.S92= | Silent (SNP) | VAF 76/94 reads (81%) | catalogued as rs762459415; called by muse, varscan2
- KRT26 | c.624G>A p.E208= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as rs1484464132; called by muse, mutect2, varscan2
- LRRTM2 | c.1440C>T p.D480= | Silent (SNP) | VAF 110/227 reads (48%) | called by muse, mutect2, varscan2
- LRRTM3 | c.1005G>A p.E335= | Silent (SNP) | VAF 70/134 reads (52%) | catalogued as COSV63665161; called by muse, mutect2, varscan2
- MAGEL2 | c.1662G>A p.A554= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs910557950, COSV100045889; called by muse, mutect2, varscan2
- MAP6 | c.1152A>G p.P384= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as rs1257498950; called by muse, mutect2, varscan2
- MSANTD2 | c.43C>T p.L15= | Silent (SNP) | VAF 41/85 reads (48%) | called by muse, mutect2, varscan2
- NLGN4X | c.1095C>T p.Y365= | Silent (SNP) | VAF 54/58 reads (93%) | catalogued as rs1270495452, COSV52024376; called by muse, mutect2, varscan2
- NT5M | c.534G>A p.P178= | Silent (SNP) | VAF 60/122 reads (49%) | catalogued as rs775411806, COSV66518528; called by muse, mutect2, varscan2
- OBSCN | c.312G>A p.A104= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs1234843230, COSV52786164; called by muse, mutect2, varscan2
- OR5D13 | c.693A>G p.R231= | Silent (SNP) | VAF 64/154 reads (42%) | called by muse, mutect2, varscan2
- PLCB1 | c.2652T>G p.A884= | Silent (SNP) | VAF 70/165 reads (42%) | called by muse, mutect2, varscan2
- POPDC3 | c.435C>T p.A145= | Silent (SNP) | VAF 78/170 reads (46%) | catalogued as COSV54646104; called by muse, mutect2, varscan2
- PTCD1 | c.1524G>A p.L508= | Silent (SNP) | VAF 80/215 reads (37%) | called by muse, mutect2, varscan2
- RBM42 | c.495G>A p.V165= | Silent (SNP) | VAF 95/188 reads (51%) | called by muse, mutect2, varscan2
- RYK | c.426T>C p.V142= | Silent (SNP) | VAF 55/103 reads (53%) | called by muse, mutect2, varscan2
- TBCB | c.585C>A p.V195= | Silent (SNP) | VAF 80/172 reads (47%) | catalogued as COSV55692340; called by muse, mutect2, varscan2
- THOC1 | c.1710A>G p.T570= | Silent (SNP) | VAF 82/151 reads (54%) | called by muse, mutect2, varscan2
- WDR83 | c.336G>A p.V112= | Silent (SNP) | VAF 47/107 reads (44%) | catalogued as rs767634370; called by muse, mutect2, varscan2
- ZNF335 | c.2883G>A p.L961= | Silent (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- ZNF512B | c.1551G>C p.V517= | Silent (SNP) | VAF 76/173 reads (44%) | called by muse, mutect2, varscan2
- AC027612.1 | n.1754G>A | RNA (SNP) | VAF 9/35 reads (26%) | catalogued as rs561551101; called by muse, varscan2
- ACAD8 | c.-32G>A | 5'UTR (SNP) | VAF 20/67 reads (30%) | called by muse, varscan2
- ACTR3 | c.540+55T>C | Intron (SNP) | VAF 38/86 reads (44%) | called by muse, mutect2, varscan2
- AGPAT4 | c.348+4912G>T | Intron (SNP) | VAF 80/189 reads (42%) | called by muse, mutect2, varscan2
- AKNA | c.*598G>A | 3'UTR (SNP) | VAF 66/134 reads (49%) | called by muse, mutect2, varscan2
- AL138930.1 | n.115+5368T>A | Intron (SNP) | VAF 43/94 reads (46%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499190 T>G | 5'Flank (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- APBB1IP | c.453+536T>C | Intron (SNP) | VAF 36/97 reads (37%) | called by muse, mutect2, varscan2
- AQP2 | c.*1713C>T | 3'UTR (SNP) | VAF 116/215 reads (54%) | catalogued as rs913827488; called by muse, mutect2
- ARHGEF7 | c.*1231T>G | 3'UTR (SNP) | VAF 45/51 reads (88%) | called by muse, mutect2, varscan2
- ATF2 | c.*1151C>G | 3'UTR (SNP) | VAF 28/45 reads (62%) | called by muse, mutect2, varscan2
- ATP11C | c.-72T>C | 5'UTR (SNP) | VAF 43/44 reads (98%) | catalogued as rs1467283315; called by muse, mutect2, varscan2
- ATXN3 | c.*3200G>A | 3'UTR (SNP) | VAF 39/45 reads (87%) | called by muse, mutect2, varscan2
- AVPR1A | c.*185A>G | 3'UTR (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- B3GAT2 | c.*4253dup | 3'UTR (INS) | VAF 51/105 reads (49%) | catalogued as rs1181739809; called by mutect2, varscan2
- BAG6 | c.3426+134G>A | Intron (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021400 A>G | 5'Flank (SNP) | VAF 53/115 reads (46%) | called by muse, varscan2
- BCL7A | chr12:122021401 G>A | 5'Flank (SNP) | VAF 52/115 reads (45%) | catalogued as rs547304687, COSV55852870; called by muse, varscan2
- BCL7A | chr12:122021430 C>T | 5'Flank (SNP) | VAF 62/122 reads (51%) | catalogued as rs576508090; called by muse, varscan2
- BEST1 | chr11:61965273 C>T | 3'Flank (SNP) | VAF 49/95 reads (52%) | called by muse, mutect2, varscan2
- C7orf65 | n.2234T>A | RNA (SNP) | VAF 81/162 reads (50%) | catalogued as rs564535065; called by muse, mutect2, varscan2
- CACNA1C | c.3828+388dup | Intron (INS) | VAF 74/211 reads (35%) | called by mutect2, pindel, varscan2
- CALHM5 | c.*5543_*5548del | 3'UTR (DEL) | VAF 3/37 reads (8%) | called by pindel, varscan2*
- CALN1 | c.*3457C>T | 3'UTR (SNP) | VAF 32/83 reads (39%) | called by muse, mutect2, varscan2
- CCM2 | c.31-10925C>T | Intron (SNP) | VAF 69/133 reads (52%) | called by muse, mutect2, varscan2
- CDC42SE2 | c.*939G>A | 3'UTR (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- CDH7 | chr18:65885032 A>C | 3'Flank (SNP) | VAF 35/78 reads (45%) | called by muse, mutect2, varscan2
- CDH8 | c.*679G>T | 3'UTR (SNP) | VAF 131/141 reads (93%) | catalogued as rs776781338; called by muse, mutect2, varscan2
- CHD4 | c.*485C>T | 3'UTR (SNP) | VAF 3/40 reads (8%) | catalogued as rs1012261922; called by muse, mutect2
- CNNM1 | c.*2015del | 3'UTR (DEL) | VAF 39/81 reads (48%) | called by mutect2, varscan2
- COLGALT2 | c.*2236del | 3'UTR (DEL) | VAF 54/110 reads (49%) | catalogued as rs924230076; called by mutect2, varscan2
- CRIM1 | c.1501+28T>A | Intron (SNP) | VAF 43/113 reads (38%) | called by muse, mutect2, varscan2
- CYHR1 | c.246+508C>G | Intron (SNP) | VAF 49/51 reads (96%) | called by muse, mutect2, varscan2
- CYYR1 | c.-47C>T | 5'UTR (SNP) | VAF 46/96 reads (48%) | catalogued as rs992870234, COSV100177760; called by muse, mutect2, varscan2
- DUT | c.281-129G>A | Intron (SNP) | VAF 47/97 reads (48%) | catalogued as rs1203897460; called by muse, mutect2, varscan2
- EIF2S3 | c.*1083_*1095del | 3'UTR (DEL) | VAF 57/66 reads (86%) | called by mutect2, pindel, varscan2
- EIF5AL1 | c.*2795A>C | 3'UTR (SNP) | VAF 74/182 reads (41%) | catalogued as rs528369417, COSV73123125, COSV73123183; called by muse, varscan2
- ENAH | c.*1316A>G | 3'UTR (SNP) | VAF 57/121 reads (47%) | called by muse, mutect2, varscan2
- EXOC6B | c.-114C>A | 5'UTR (SNP) | VAF 51/108 reads (47%) | called by muse, mutect2, varscan2
- EXT1 | c.*210G>T | 3'UTR (SNP) | VAF 26/30 reads (87%) | called by muse, mutect2, varscan2
- FAM122B | c.-925G>C | 5'UTR (SNP) | VAF 9/10 reads (90%) | called by muse, mutect2, varscan2
- FAM72B | c.-210G>A | 5'UTR (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- FASTKD2 | c.*627_*629del | 3'UTR (DEL) | VAF 43/105 reads (41%) | catalogued as rs1197643537; called by mutect2, pindel, varscan2
- FAT4 | c.*778A>C | 3'UTR (SNP) | VAF 38/39 reads (97%) | called by muse, mutect2, varscan2
- FBXO4 | c.*262T>A | 3'UTR (SNP) | VAF 32/73 reads (44%) | called by muse, mutect2, varscan2
- FBXO42 | c.*3756A>C | 3'UTR (SNP) | VAF 43/49 reads (88%) | called by muse, mutect2, varscan2
- FCGR2A | c.*609T>C | 3'UTR (SNP) | VAF 30/77 reads (39%) | called by muse, varscan2
- FTO | c.*4159A>T | 3'UTR (SNP) | VAF 31/49 reads (63%) | called by muse, mutect2, varscan2
- FYCO1 | c.*3314G>T | 3'UTR (SNP) | VAF 44/93 reads (47%) | called by muse, mutect2, varscan2
- GABRA2 | c.187+20478G>T | Intron (SNP) | VAF 22/22 reads (100%) | called by muse, mutect2, varscan2
- GNPDA2 | c.769+1842C>T | Intron (SNP) | VAF 13/13 reads (100%) | called by muse, mutect2, varscan2
- GPD2 | c.*2604C>T | 3'UTR (SNP) | VAF 37/75 reads (49%) | called by muse, mutect2, varscan2
- GRB2 | c.-137-38C>G | Intron (SNP) | VAF 45/108 reads (42%) | called by muse, mutect2, varscan2
- GRIK2 | c.952-54713T>C | Intron (SNP) | VAF 21/34 reads (62%) | called by muse, mutect2, varscan2
- IGLC2 | c.*109del | 3'UTR (DEL) | VAF 54/93 reads (58%) | called by pindel, varscan2
- KIAA1549L | c.-3G>T | 5'UTR (SNP) | VAF 96/220 reads (44%) | called by muse, mutect2, varscan2
- KIFC3 | c.1513-29dup | Intron (INS) | VAF 22/27 reads (81%) | catalogued as rs1302775063; called by mutect2, varscan2
- KLF13 | c.*1197A>C | 3'UTR (SNP) | VAF 111/211 reads (53%) | called by muse, mutect2, varscan2
- KRTAP2-3 | c.*247del | 3'UTR (DEL) | VAF 56/122 reads (46%) | catalogued as rs968973148; called by mutect2, varscan2
- LIN28B | c.*3526C>T | 3'UTR (SNP) | VAF 87/218 reads (40%) | called by muse, mutect2, varscan2
- LINC02228 | n.270G>A | RNA (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- LPP | c.*5431T>A | 3'UTR (SNP) | VAF 41/84 reads (49%) | called by muse, mutect2, varscan2
- LTB | c.162+165T>A | Intron (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
- LTC4S | c.*60G>A | 3'UTR (SNP) | VAF 28/49 reads (57%) | catalogued as rs1198364659; called by muse, mutect2, varscan2
- LUZP2 | c.*3032A>T | 3'UTR (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- MAPK12 | c.692-56G>C | Intron (SNP) | VAF 71/81 reads (88%) | called by muse, mutect2, varscan2
- MARK3 | c.-299G>A | 5'UTR (SNP) | VAF 17/18 reads (94%) | called by muse, mutect2, varscan2
- MGAT4B | c.911-63G>T | Intron (SNP) | VAF 41/81 reads (51%) | called by muse, mutect2, varscan2
- MGST1 | c.*976C>T | 3'UTR (SNP) | VAF 22/40 reads (55%) | catalogued as rs866503434; called by muse, varscan2
- MIR5195 | chr14:106851274 G>C | 5'Flank (SNP) | VAF 96/102 reads (94%) | catalogued as rs753218887; called by muse, mutect2, varscan2
- MIR520C | n.50A>C | RNA (SNP) | VAF 6/178 reads (3%) | called by muse, mutect2
- MMP26 | c.-145+92701C>T | Intron (SNP) | VAF 67/136 reads (49%) | catalogued as rs936313599; called by muse, mutect2, varscan2
- MPV17L2 | c.*408G>C | 3'UTR (SNP) | VAF 67/140 reads (48%) | called by muse, mutect2, varscan2
- MSRB3 | c.*2119del | 3'UTR (DEL) | VAF 42/103 reads (41%) | catalogued as rs1165806331; called by mutect2, varscan2
- MTR | c.*651G>A | 3'UTR (SNP) | VAF 38/78 reads (49%) | catalogued as rs746740881; called by muse, mutect2, varscan2
- MYC | c.*387dup | 3'UTR (INS) | VAF 26/44 reads (59%) | called by mutect2, pindel, varscan2
- NANP | c.*723A>G | 3'UTR (SNP) | VAF 33/91 reads (36%) | called by muse, mutect2, varscan2
- NLGN1 | c.493+454T>G | Intron (SNP) | VAF 66/147 reads (45%) | called by muse, mutect2, varscan2
- NPEPL1 | c.1126-181G>A | Intron (SNP) | VAF 6/15 reads (40%) | catalogued as rs780020665; called by muse, varscan2
- NRG1 | c.700+891G>T | Intron (SNP) | VAF 29/35 reads (83%) | called by muse, mutect2, varscan2
- NRXN1 | c.832+1958T>C | Intron (SNP) | VAF 68/160 reads (43%) | catalogued as rs1050665611; called by muse, mutect2, varscan2
- NUCKS1 | c.*2537T>A | 3'UTR (SNP) | VAF 42/102 reads (41%) | called by muse, mutect2, varscan2
- NUP210 | c.*45G>T | 3'UTR (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- OPCML | c.-75G>A | 5'UTR (SNP) | VAF 95/183 reads (52%) | catalogued as rs914885577; called by muse, mutect2, varscan2
- OR10V2P | n.507C>A | RNA (SNP) | VAF 61/145 reads (42%) | catalogued as rs973105039; called by muse, mutect2, varscan2
- OR5H6 | chr3:98264256 C>A | 5'Flank (SNP) | VAF 74/162 reads (46%) | called by muse, mutect2, varscan2
- OSBPL10 | c.*1511A>G | 3'UTR (SNP) | VAF 31/68 reads (46%) | called by muse, mutect2, varscan2
- PCDH11X | c.*1962A>C | 3'UTR (SNP) | VAF 56/62 reads (90%) | called by muse, mutect2, varscan2
- PCDHA7 | c.-91C>G | 5'UTR (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- PDGFD | c.*1722T>C | 3'UTR (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- PIAS2 | c.1508+100A>C | Intron (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- PLCB1 | c.3423+12029C>A | Intron (SNP) | VAF 55/128 reads (43%) | called by muse, mutect2, varscan2
- PLCXD3 | c.*4584T>C | 3'UTR (SNP) | VAF 57/113 reads (50%) | called by muse, mutect2, varscan2
- PNMA3 | c.*1131C>T | 3'UTR (SNP) | VAF 13/62 reads (21%) | catalogued as rs1348130159; called by muse, mutect2, varscan2
- PRDM15 | c.*18T>A | 3'UTR (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- PRELID1P6 | n.256G>A | RNA (SNP) | VAF 95/187 reads (51%) | called by muse, mutect2, varscan2
- PRKCB | c.1864-3330C>T | Intron (SNP) | VAF 49/52 reads (94%) | called by muse, mutect2, varscan2
- PRR14L | c.*2068T>C | 3'UTR (SNP) | VAF 61/67 reads (91%) | called by muse, mutect2, varscan2
- PSTPIP1 | c.839-217C>A | Intron (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- PTPRS | c.3935+19C>T | Intron (SNP) | VAF 60/104 reads (58%) | called by muse, mutect2, varscan2
- PUF60 | c.*174C>T | 3'UTR (SNP) | VAF 36/41 reads (88%) | called by muse, mutect2, varscan2
- RALGPS1 | c.*553G>A | 3'UTR (SNP) | VAF 40/88 reads (45%) | catalogued as rs559954937; called by muse, varscan2
- RFTN1 | c.*132G>C | 3'UTR (SNP) | VAF 53/112 reads (47%) | called by muse, mutect2, varscan2
- RNF128 | c.*263A>G | 3'UTR (SNP) | VAF 22/22 reads (100%) | called by muse, mutect2, varscan2
- RPP40 | c.123+53G>A | Intron (SNP) | VAF 14/158 reads (9%) | catalogued as rs1435083658; called by muse, mutect2
- RPS6KC1 | c.*1860A>C | 3'UTR (SNP) | VAF 40/79 reads (51%) | catalogued as COSV100874172; called by muse, mutect2, varscan2
- SAMD5 | c.*2664A>G | 3'UTR (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- SCAP | c.253-116G>C | Intron (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- SCN11A | c.4327+1031G>T | Intron (SNP) | VAF 33/77 reads (43%) | called by muse, mutect2, varscan2
- SEMA3E | c.*2697G>T | 3'UTR (SNP) | VAF 41/85 reads (48%) | called by muse, mutect2, varscan2
- SHTN1 | c.*4223T>G | 3'UTR (SNP) | VAF 51/92 reads (55%) | called by muse, mutect2, varscan2
- SIGLEC6 | c.*599del | 3'UTR (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel, varscan2
- SMURF1 | c.*2885T>A | 3'UTR (SNP) | VAF 53/115 reads (46%) | catalogued as rs1002559195; called by muse, mutect2, varscan2
- SNRPN | c.3+274A>C | Intron (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- SSR1 | c.*8056G>A | 3'UTR (SNP) | VAF 44/91 reads (48%) | catalogued as rs1405789992; called by muse, mutect2, varscan2
- STMP1 | c.*7C>T | 3'UTR (SNP) | VAF 91/190 reads (48%) | catalogued as rs1563150528; called by muse, mutect2, varscan2
- STS | c.*662T>G | 3'UTR (SNP) | VAF 79/80 reads (99%) | called by muse, mutect2, varscan2
- STS | c.*804C>A | 3'UTR (SNP) | VAF 44/44 reads (100%) | called by muse, mutect2, varscan2
- SV2C | c.*4846C>G | 3'UTR (SNP) | VAF 35/88 reads (40%) | called by muse, mutect2, varscan2
- SVIP | c.*3763A>C | 3'UTR (SNP) | VAF 44/85 reads (52%) | called by muse, mutect2, varscan2
- SYNM | c.*701T>G | 3'UTR (SNP) | VAF 47/120 reads (39%) | called by muse, mutect2, varscan2
- SYT5 | c.961-31C>A | Intron (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
- TAF1D | c.-168G>T | 5'UTR (SNP) | VAF 86/193 reads (45%) | called by muse, mutect2, varscan2
- TENM1 | c.*1593A>T | 3'UTR (SNP) | VAF 37/41 reads (90%) | called by muse, mutect2, varscan2
- THBD | c.*508T>C | 3'UTR (SNP) | VAF 30/65 reads (46%) | catalogued as rs1423398386; called by muse, mutect2, varscan2
- THOC5 | chr22:29507694 C>G | 3'Flank (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- TMEM127 | c.*3145C>T | 3'UTR (SNP) | VAF 59/111 reads (53%) | called by muse, mutect2, varscan2
- TMEM183B | n.650G>A | RNA (SNP) | VAF 67/141 reads (48%) | catalogued as rs754915624; called by muse, mutect2, varscan2
- TMEM53 | c.*894G>T | 3'UTR (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- TMEM65 | c.-294_-282del | 5'UTR (DEL) | VAF 45/59 reads (76%) | called by mutect2, pindel, varscan2
- TMSB4X | chrX:12975348 G>T | 5'Flank (SNP) | VAF 55/57 reads (96%) | called by muse, varscan2
- TMSB4X | chrX:12975349 G>T | 5'Flank (SNP) | VAF 53/55 reads (96%) | catalogued as COSV104432400; called by muse, varscan2
- TMSB4X | chrX:12975428 G>C | 5'Flank (SNP) | VAF 76/79 reads (96%) | catalogued as COSV66081661; called by muse, varscan2
- TMSB4X | c.-85G>A | 5'UTR (SNP) | VAF 86/88 reads (98%) | catalogued as rs760793307, COSV66081781; called by muse, mutect2, varscan2
- TOP2B | chr3:25664882 C>G | 5'Flank (SNP) | VAF 6/173 reads (3%) | called by muse, mutect2
- TRPM7 | c.*753A>G | 3'UTR (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- TRPS1 | c.-3+592C>T | Intron (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
- UBAP2L | c.*214T>C | 3'UTR (SNP) | VAF 99/211 reads (47%) | catalogued as rs1453030324, COSV55173988; called by muse, mutect2, varscan2
- UGT8 | c.*280A>G | 3'UTR (SNP) | VAF 26/29 reads (90%) | called by muse, mutect2, varscan2
- UGT8 | c.*1160A>T | 3'UTR (SNP) | VAF 36/39 reads (92%) | called by muse, mutect2, varscan2
- UGT8 | c.*1570A>G | 3'UTR (SNP) | VAF 25/29 reads (86%) | called by muse, mutect2, varscan2
- VAX1 | chr10:117131514 C>G | 3'Flank (SNP) | VAF 53/95 reads (56%) | called by muse, mutect2, varscan2
- VPS41 | c.*3012G>T | 3'UTR (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- WNT7B | c.*695G>A | 3'UTR (SNP) | VAF 49/59 reads (83%) | called by muse, mutect2, varscan2
- ZNF326 | c.*828C>T | 3'UTR (SNP) | VAF 34/41 reads (83%) | called by muse, mutect2, varscan2
- ZNF653 | c.*83G>A | 3'UTR (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2
- ZNF717 | c.*208C>A | 3'UTR (SNP) | VAF 30/83 reads (36%) | called by muse, mutect2, varscan2
- ZNF804A | c.*33G>T | 3'UTR (SNP) | VAF 67/124 reads (54%) | catalogued as rs1407337037; called by muse, mutect2, varscan2
